Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4455, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4455-01A (Primary Tumor).

■
Diagnosis/diagnoses:

Residual gastrectomy preparation of a stomach that had previously undergone B-II gastrectomy showing tumor-free resection margins and the inclusion of a poorly differentiated, highly mucigenous or mucinous adenocarcinoma with an extensive signet ring cell component (so-called gastric carcinoma of the diffuse type) in the region of the lesser curvature covering almost the entire gastric stump from the heart to the anastomosis, with infiltration of the subserosa and two regional lymph node metastases ■, pT2b pN1 2/17 L0 ■

Source: NCI Genomic Data Commons file b1a11a05-8171-4a33-a095-90de847790ed (TCGA-CG-4455.E6902D2D-C5F4-46DC-A72E-156C4267397D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).